MMRF case MMRF_1324 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/273a1d4c-807a-4470-936d-e76e1e2ae190

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.7 years (22,526 days); ISS stage: II; Days to last known disease status: 1,537 days (4.2 years); Days to last follow up: 1,537 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 607 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 3 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 334 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 424 days (1.2 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days; Days to treatment end: 607 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 623 days (1.7 years); Days to treatment end: 680 days (1.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 623 days (1.7 years); Days to treatment end: 730 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 680 days (1.9 years); Days to treatment end: 730 days (2.0 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 774 days (2.1 years); Days to treatment end: 774 days (2.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 775 days (2.1 years); Days to treatment end: 775 days (2.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 775 days (2.1 years); Days to treatment end: 775 days (2.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 880 days (2.4 years); Days to treatment end: 1,446 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 953 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1760 mg/dL; Immunoglobulin G 4.47 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 5.04 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 6.38 mmol/L; C-Reactive Protein 0.17 mg/dL.
- Day 75 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 6.34 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 5.39 mmol/L.
- Day 173 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 7.82 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 8.58 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 8.09 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 368 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 11.6 mmol/L.
- Day 424 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 8.24 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Total Protein 6.8 g/dL; Glucose 6.71 mmol/L.
- Day 550 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 8 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Glucose 6.22 mmol/L.
- Day 633 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.87 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 8.5 g/dL; Glucose 4.29 mmol/L.
- Day 718 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.718 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.88 mmol/L.
- Day 795 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.859 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 7.54 mmol/L.
- Day 893 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 9.3 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 998 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 7.86 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 7.7 mmol/L.
- Day 1,076 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.33 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6 mmol/L.
- Day 1,153 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.94 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 1.52 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 5.7 g/dL; Glucose 9.63 mmol/L.
- Day 1,223 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 6.82 mmol/L.
- Day 1,300 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 7.54 mmol/L.
- Day 1,446 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 9.41 mmol/L.
- Day 1,537 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.943 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 15.7 mmol/L.

Other clinical attributes
- Day -2: Weight: 67 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1324_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1324_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
- Sample MMRF_1324_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 257 days.
